Somatic mutation profile of tumor specimen TCGA-CQ-6222-01A (aliquot TCGA-CQ-6222-01A-11D-1912-08) from TCGA case TCGA-CQ-6222, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.9 years (23,326 days).
Specimen TCGA-CQ-6222-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf31d1ce-8a94-4946-8728-0a65d568f611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6222-10A (Blood Derived Normal), aliquot TCGA-CQ-6222-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74b43cba-bca8-4b53-920b-0e75e09a828b

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 35, Silent 10, Nonsense Mutation 5, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUSK | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as rs1487680236, COSV99504793; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.585C>G p.Y195* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as rs1316902116, COSV100748109, COSV61697765, COSV61697875; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by mutect2, varscan2
- ACACB | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs556775153, COSV58131001; called by mutect2, varscan2
- ADAMTS8 | c.1853C>A p.S618Y | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1339294420, COSV57292870, COSV99961356; called by muse, mutect2, varscan2
- AKT3 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV99796190; called by muse, mutect2, varscan2
- ANK3 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1196523308, COSV99781521; called by muse, mutect2, varscan2
- ANKZF1 | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99850787; called by muse, mutect2, varscan2
- AXIN2 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs750274537, COSV100196810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST6 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1041148351, COSV59999831; called by muse, mutect2, varscan2
- COL22A1 | c.3757C>G p.P1253A | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV100279643, COSV100279857, COSV100281128; called by muse, mutect2, varscan2
- CYP4F8 | c.1335C>A p.F445L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376016975, COSV100358191; called by muse, varscan2
- DRD5 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1187819035, COSV100431966; called by muse, mutect2, varscan2
- GLB1 | c.1832C>T p.S611L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV100257606; called by muse, mutect2
- HIVEP1 | c.6551A>G p.D2184G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs373379055; called by muse, mutect2, varscan2
- IARS1 | c.3067A>T p.N1023Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100986725; called by muse, mutect2, varscan2
- INPP5J | c.1325C>T p.T442I (on ENST00000331075 / NM_001284285.2; = p.T74I on NM_001002837.2) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100459675; called by muse, mutect2
- JCAD | c.3295C>T p.L1099F | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948515; called by muse, mutect2
- KDM4C | c.833A>T p.H278L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185039; called by muse, mutect2
- MDN1 | c.13882T>C p.S4628P | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV101021654; called by muse, mutect2
- MUC4 | c.1009C>G p.Q337E | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.044); catalogued as COSV100641678, COSV62176401; called by muse, mutect2
- NRIP1 | c.1034T>C p.V345A | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100012940; called by muse, mutect2, varscan2
- P2RX1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs558236308, COSV99844754; called by muse, mutect2, varscan2
- PARP8 | c.346-1G>T p.X116_splice | Splice Site (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99892340; called by muse, mutect2
- PIH1D1 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs753878549, COSV51807157; called by muse, mutect2
- PLAGL1 | c.782A>G p.H261R | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV99394638; called by muse, mutect2, varscan2
- PSME4 | c.4147A>G p.I1383V | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1455016526, COSV101122599; called by muse, mutect2
- RAB3GAP1 | c.2536G>T p.A846S | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as COSV99921550; called by muse, mutect2
- REG4 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs967171739, COSV56652842, COSV56654150; called by muse, mutect2
- RUSC2 | c.2582G>A p.R861Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as rs746360364, COSV100770816; called by mutect2, varscan2
- SFI1 | c.2462G>A p.R821Q (on ENST00000400288 / NM_001007467.3; = p.R790Q on NM_014775.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs764891956, COSV63475272; called by mutect2, varscan2
- SLC36A1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99695687; called by muse, mutect2
- SPATA31D1 | c.1378G>T p.V460F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); catalogued as COSV100782964; called by muse, mutect2, varscan2
- SPRYD3 | c.39C>A p.N13K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.077); catalogued as COSV100036793; called by muse, mutect2, varscan2
- TIAM2 | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1376259588, COSV99265254; called by muse, mutect2
- TULP3 | c.1237G>A p.V413M | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs773320390, COSV101237573; called by muse, mutect2
- XPO7 | c.2767G>T p.G923* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99381821; called by muse, mutect2, varscan2
- YTHDF3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as rs563216596, COSV72773380; called by muse, mutect2, varscan2
- ZNF30 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100340702; called by muse, mutect2, varscan2
- ELOVL4 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ABCC1 | c.2946C>T p.F982= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs376870080; called by muse, mutect2
- AFDN | c.4437G>A p.R1479= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100653332; called by muse, mutect2
- KCNH1 | c.2487C>T p.G829= (on ENST00000271751 / NM_172362.3; = p.G802= on NM_002238.4) | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs776217147, COSV55084673; called by muse, mutect2, varscan2
- LRP4 | c.3387C>T p.L1129= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV101066787; called by muse, mutect2, varscan2
- MARCO | c.159G>A p.L53= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs866581075, COSV100503696; called by muse, mutect2, varscan2
- MYL1 | c.18C>T p.D6= | Silent (SNP) | VAF 33/312 reads (11%) | catalogued as rs1371185555, COSV100751687, COSV100751700; called by muse, mutect2, varscan2
- PIP4K2A | c.204C>T p.A68= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100927422; called by muse, mutect2, varscan2
- PPP1R9A | c.126A>G p.E42= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99196756; called by muse, mutect2, varscan2
- SSH1 | c.1083C>T p.Y361= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as rs376321294; called by muse, mutect2, varscan2
- VIP | c.72G>A p.S24= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs535018056, COSV100923935; called by muse, mutect2, varscan2
